Gene-level copy-number profile of tumor specimen C3N-03878-01 (profiled together with C3N-03878-02) from CPTAC case C3N-03878, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 52.9 years (19,338 days).
Specimen C3N-03878-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0f86fd63-ab65-4092-87df-7d185cd882de.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03878-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/4e6d706d-35d9-43c9-a0e4-7da683f7e522

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 573; copy number 1: 125; copy number 2: 11,096; copy number 3: 2,958; copy number 4: 38,281; copy number 5: 1,084; copy number 6: 4,113; copy number 7: 21; copy number 8: 84; copy number 9: 46; copy number 10: 200; copy number 13: 15; copy number 15: 164; copy number 16: 35; copy number 17: 2; copy number 18: 65; copy number 34: 39; copy number 44: 1.

Homozygous deletions (total copy number 0; autosomes only): 56 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:27,486,247–31,637,616, 40 genes: AC099535.1, RNU1-96P, AC137675.1, Y_RNA, AC098614.1, AC098614.2, KIAA1143P2, LINC02084, EOMES, LINC01980, LINC01981, LINC01967, CMC1, AZI2, ZCWPW2, AC098650.1, FAM96AP1, AC093142.1, RBMS3, RBMS3-AS3, MESTP4, RPS12P5, RBMS3-AS2, MTND4LP9, RBMS3-AS1, AC025614.2, AC025614.1, U3, LINC01985, AC116035.1, TGFBR2, AC096921.1, AC096921.2, GADL1, MIR466, CNN2P6, RNA5SP127, H3P11, THRAP3P1, STT3B.
- chr3:31,704,058–31,796,175, 2 genes (within-gene range 0–2): OSBPL10-AS1, ZNF587P1.
- chr4:201,409–270,175, 4 genes: AC108475.1, ZNF876P, AC079140.3, AC079140.5.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–2): AL359922.1.
- chr9:21,929,457–21,995,301, 3 genes (within-gene range 0–2): ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes (within-gene range 0–2): AL449423.1, CDKN2B, UBA52P6.
- chr17:18,411,159–18,414,380, 1 gene: LINC02076.
- chr17:18,497,095–18,521,252, 2 genes (within-gene range 0–2): NOS2P2, USP32P2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 567 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:27,404,230–27,914,746, 24 genes, copy number 9: WASF2, FO393419.2, BX293535.1, AHDC1, FGR, AL031729.1, LINC02574, IFI6, AL445490.1, RNU6-949P, CHMP1AP1, RNU6-424P, FAM76A, AL020997.1, RPEP3, STX12, AL020997.2, AL020997.3, RNU6-1245P, AL020997.4, PPP1R8, SCARNA1, THEMIS2, RPA2.
- chr3:174,302,944–174,378,005, 2 genes, copy number 10: ANAPC15P2, AC069218.1.
- chr3:176,415,439–193,378,820, 304 genes, copy number 9–16 (broad region; genes not listed).
- chr3:194,276,682–197,029,817, 110 genes, copy number 10 (broad region; genes not listed).
- chr4:42,892,713–44,726,588, 20 genes, copy number 9–10: GRXCR1, AC111198.1, AC097451.1, AC098590.2, AC098590.1, LINC02383, AC114774.1, RN7SL691P, AC080132.1, RN7SL193P, NDUFB4P12, AC114757.1, LINC02475, KCTD8, AC093852.1, YIPF7, GUF1, GNPDA2, AC096586.2, AC096586.1.
- chr11:69,467,598–72,573,229, 107 genes, copy number 17–44 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 122. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
